Somatic mutation profile of tumor specimen TARGET-40-NAAEDH-01A (aliquot TARGET-40-NAAEDH-01A-01D) from TARGET case TARGET-40-NAAEDH, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.8 years (6,492 days).
Specimen TARGET-40-NAAEDH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cc3d63e-4278-45d9-8f0e-df6e43a1c985.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAEDH-10A (Blood Derived Normal), aliquot TARGET-40-NAAEDH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bb1f417-54e6-42e7-893f-90eda79ce159

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD1 | c.8423G>T p.R2808L (on ENST00000520002; = p.R2807L on NM_033225.6) | Missense Mutation (SNP) | VAF 42/467 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs774812490, COSV59359077; called by muse, mutect2
- DNAH9 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV52355426, COSV52378439; called by muse, varscan2
- SH3BP4 | c.992A>G p.Q331R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as rs780844581; called by muse, mutect2, varscan2
- CLCN5 | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 162/204 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- FAM171A1 | c.1371C>G p.Y457* | Nonsense Mutation (SNP) | VAF 61/267 reads (23%) | called by muse, mutect2, varscan2
- LAMA1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP2 | c.931T>C p.S311P | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MED25 | c.1165C>A p.L389I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRDM15 | c.582C>G p.H194Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2
- TDRD1 | c.2890+1G>C p.X964_splice | Splice Site (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- VPS29 | c.356T>A p.F119Y | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ALMS1 | c.2160G>A p.E720= | Silent (SNP) | VAF 43/228 reads (19%) | called by muse, mutect2
